Somatic mutation profile of tumor specimen TCGA-UB-A7ME-01A (aliquot TCGA-UB-A7ME-01A-11D-A33K-10) from TCGA case TCGA-UB-A7ME, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 51.6 years (18,846 days).
Specimen TCGA-UB-A7ME-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e5b5b55-1b12-4492-8c80-74e9e349e394.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UB-A7ME-10A (Blood Derived Normal), aliquot TCGA-UB-A7ME-10A-01D-A33K-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5275c9f9-798a-464c-8fdc-4d5c0744d6ce

The open-access MAF lists 99 somatic variants for this specimen: 74 protein-altering or splice-affecting, 23 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 23, Splice Site 4, Frame Shift Del 2, Nonsense Mutation 2, Intron 1, RNA 1, In Frame Del 1, Nonstop Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AQR | c.4144A>T p.T1382S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as COSV50030989; called by muse, mutect2, varscan2
- ARID1A | c.3002C>G p.S1001C | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61374350; called by muse, mutect2, varscan2
- ARID3A | c.1496-2A>T p.X499_splice | Splice Site (SNP) | VAF 51/140 reads (36%) | catalogued as COSV55043815, COSV55044153; called by muse, mutect2, varscan2
- BCL11B | c.1365C>G p.Y455* (on ENST00000357195 / NM_001282237.2; = p.Y384* on NM_022898.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as COSV61734646, COSV61734990; called by muse, mutect2, varscan2
- BMP5 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 137/411 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752442881, COSV63702034; called by muse, mutect2, varscan2
- C1QTNF2 | c.733G>A p.D245N (on ENST00000393975; = p.D200N on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs752487351, COSV67432497; called by muse, mutect2, varscan2
- CAGE1 | c.2202A>T p.K734N (on ENST00000512086; = p.K598N on NM_205864.3) | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV57075844; called by muse, mutect2, varscan2
- CASP8AP2 | c.2004G>T p.M668I | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV52746005; called by muse, mutect2, varscan2
- CCDC80 | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.173); catalogued as COSV52815796; called by muse, mutect2, varscan2
- CENPE | c.1714G>T p.D572Y | Missense Mutation (SNP) | VAF 67/290 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54378741; called by muse, mutect2, varscan2
- CEP89 | c.1931A>T p.N644I | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV59863112; called by muse, mutect2, varscan2
- CFAP61 | c.2665G>A p.A889T | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV55623771, COSV55648566; called by muse, mutect2, varscan2
- CSHL1 | c.196T>A p.Y66N | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.63); catalogued as COSV51987620; called by muse, mutect2, varscan2
- CST5 | c.428A>T p.*143Lext*9 | Nonstop Mutation (SNP) | VAF 53/134 reads (40%) | catalogued as COSV59014142, COSV59014330; called by muse, mutect2, varscan2
- CXCR2 | c.263T>A p.L88Q | Missense Mutation (SNP) | VAF 72/178 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59280211; called by muse, mutect2, varscan2
- CYP8B1 | c.1121A>G p.Y374C | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as COSV60225962; called by muse, mutect2, varscan2
- DEFB119 | c.40A>T p.I14L | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs1364854079, COSV59265999; called by muse, mutect2
- DICER1 | c.5529A>T p.E1843D | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.106); catalogued as COSV58617220; called by muse, mutect2, varscan2
- EFCAB14 | c.911A>T p.Q304L | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV64238553; called by muse, mutect2, varscan2
- FASTKD2 | c.1996G>T p.G666C | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52697749; called by muse, mutect2, varscan2
- G2E3 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs767991087, COSV52839325; called by muse, mutect2, varscan2
- GFI1 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.267); catalogued as COSV54042137; called by muse, mutect2, varscan2
- KIAA1755 | c.1948G>A p.A650T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1455198884, COSV54074885; called by muse, mutect2
- LMNB2 | c.845A>T p.Y282F | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as COSV100322008, COSV57587252; called by muse, mutect2, varscan2
- MAP3K12 | c.795C>A p.S265R | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57232108; called by muse, mutect2, varscan2
- MED28 | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV52845954; called by muse, mutect2, varscan2
- MUC16 | c.5821A>T p.I1941F | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.702); catalogued as rs752320719, COSV67455267; called by muse, mutect2, varscan2
- MYH14 | c.4625A>T p.K1542M | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51813434; called by muse, mutect2, varscan2
- NAPB | c.712T>G p.S238A | Missense Mutation (SNP) | VAF 104/422 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as COSV63326112; called by muse, mutect2, varscan2
- NCOA7 | c.308A>C p.K103T | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57653827; called by muse, mutect2, varscan2
- NLGN1 | c.1058A>T p.H353L | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.102); catalogued as COSV64327560; called by muse, mutect2, varscan2
- OGFR | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.139); catalogued as COSV51697685; called by muse, mutect2, varscan2
- PABPC5 | c.436G>T p.G146C | Missense Mutation (SNP) | VAF 73/107 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57039791; called by muse, mutect2, varscan2
- PCDHB16 | c.603T>A p.D201E | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53359934; called by muse, mutect2, varscan2
- PCYT2 | c.455G>T p.R152L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58710997, COSV58712950; called by muse, mutect2, varscan2
- PDE3A | c.2218C>A p.H740N | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as COSV62970282; called by muse, mutect2, varscan2
- PMFBP1 | c.108G>T p.Q36H | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.161); catalogued as COSV52822094; called by muse, mutect2, varscan2
- PTGS1 | c.353T>G p.V118G | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV56290900; called by muse, mutect2, varscan2
- RAB3GAP1 | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 25/132 reads (19%) | catalogued as rs1310680343, CM133230, COSV51480371; called by muse, mutect2, varscan2
- RIMS2 | c.1858A>G p.I620V (on ENST00000666250 / NM_001348490.2; = p.I428V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/141 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51666565; called by muse, mutect2, varscan2
- RIOK2 | c.1037A>G p.E346G | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV51611812; called by muse, mutect2
- RMI1 | c.184A>T p.R62W | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57935790; called by muse, mutect2, varscan2
- RP1 | c.554A>T p.Q185L | Missense Mutation (SNP) | VAF 100/185 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV55113457; called by muse, mutect2, varscan2
- RYR1 | c.1442G>C p.G481A | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62093234, COSV62102317; called by muse, mutect2, varscan2
- RYR2 | c.10187T>G p.F3396C | Missense Mutation (SNP) | VAF 70/160 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63674673; called by muse, mutect2
- SEC14L1 | c.64-2A>T p.X22_splice | Splice Site (SNP) | VAF 12/39 reads (31%) | catalogued as COSV66721455; called by muse, mutect2, varscan2
- SERPINB10 | c.213A>C p.E71D | Missense Mutation (SNP) | VAF 98/277 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.013); catalogued as COSV53072505; called by mutect2, varscan2
- SERPINB3 | c.1055T>A p.F352Y | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT tolerated (0.74); PolyPhen benign (0.012); catalogued as rs773929167, COSV52190483; called by muse, mutect2, varscan2
- SH3TC2 | c.3407A>T p.Q1136L | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV60462065; called by muse, mutect2, varscan2
- SH3YL1 | c.292-1G>A p.X98_splice | Splice Site (SNP) | VAF 16/81 reads (20%) | catalogued as rs889770485, COSV62155810; called by muse, mutect2, varscan2
- SKOR1 | c.2836A>C p.K946Q | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58244779; called by muse, mutect2, varscan2
- SLC25A19 | c.658C>G p.L220V | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.513); catalogued as COSV57467035; called by muse, mutect2, varscan2
- SLC26A7 | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52589004; called by muse, mutect2, varscan2
- SLC38A1 | c.86A>G p.N29S | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.332); catalogued as rs375543520; called by muse, mutect2, varscan2
- SLC6A17 | c.404T>A p.I135K | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV58992096; called by muse, mutect2
- SMTN | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as rs1436277839, COSV60776562; called by muse, mutect2, varscan2
- SMYD1 | c.814T>A p.F272I | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV70224762; called by muse, mutect2, varscan2
- SPTBN4 | c.2809G>A p.V937I | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as rs754511407, COSV58946069; called by muse, mutect2, varscan2
- SRRM2 | c.2228C>T p.S743F | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as COSV57070670; called by muse, mutect2, varscan2
- TCEA1 | c.881G>A p.C294Y | Missense Mutation (SNP) | VAF 51/371 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67172273; called by muse, mutect2, varscan2
- THEMIS | c.894A>T p.Q298H | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.141); catalogued as COSV64070089; called by muse, mutect2, varscan2
- TPRN | c.1874C>T p.S625L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1386556020, COSV58806852; called by muse, mutect2
- TTI1 | c.114A>T p.Q38H | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV65061042; called by muse, mutect2, varscan2
- XIRP2 | c.5537C>A p.A1846D (on ENST00000628543; = p.A2021D on NM_152381.6) | Missense Mutation (SNP) | VAF 47/277 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54690273; called by muse, mutect2, varscan2
- ZNF14 | c.782G>A p.S261N | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV59848814; called by muse, mutect2, varscan2
- ZNF334 | c.1996C>T p.R666C | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs763384880, COSV61617978; called by muse, mutect2
- ZNF383 | c.1390G>C p.D464H | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV61938796; called by muse, mutect2, varscan2
- ZNF576 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV60670404; called by muse, mutect2, varscan2
- ARHGEF15 | c.770_781del p.G257_A260del | In Frame Del (DEL) | VAF 17/38 reads (45%) | called by mutect2, pindel, varscan2
- FASN | c.6509del p.L2170Pfs*48 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | called by mutect2, pindel, varscan2
- IGHA1 | c.538T>G p.C180G | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- KRTAP10-12 | c.444_445insTT p.Q149Ffs*121 | Frame Shift Ins (INS) | VAF 10/24 reads (42%) | called by mutect2, pindel*, varscan2
- MATN4 | c.889+1del p.X297_splice (on ENST00000372754; = p.X256_splice on NM_003833.4) | Splice Site (DEL) | VAF 24/108 reads (22%) | called by mutect2, pindel, varscan2
- USP48 | c.2753del p.K918Rfs*8 | Frame Shift Del (DEL) | VAF 15/56 reads (27%) | called by mutect2, pindel, varscan2
- AASDH | c.1563A>G p.P521= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV52705271; called by muse, mutect2, varscan2
- ARNT | c.1845A>T p.S615= | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as COSV62230067, COSV62230154; called by muse, mutect2, varscan2
- ART5 | c.66T>A p.A22= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as COSV51703629; called by muse, mutect2, varscan2
- BBS12 | c.1449T>C p.D483= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV58561670; called by muse, mutect2, varscan2
- COL13A1 | c.1686A>T p.P562= (on ENST00000398978 / NM_001130103.2; = p.P543= on NM_080800.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as COSV62568214; called by muse, mutect2, varscan2
- CRACD | c.468C>A p.A156= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as rs372203605; called by muse, mutect2, varscan2
- FBH1 | c.135G>C p.P45= (on ENST00000362091 / NM_178150.3; = p.P96= on NM_032807.4) | Silent (SNP) | VAF 35/112 reads (31%) | catalogued as COSV62981989, COSV62982078; called by muse, mutect2, varscan2
- FGF18 | c.291C>T p.V97= | Silent (SNP) | VAF 22/125 reads (18%) | catalogued as rs774406179, COSV51125778; called by muse, mutect2, varscan2
- FLG | c.11250G>A p.A3750= | Silent (SNP) | VAF 25/223 reads (11%) | catalogued as rs201725426, COSV64239015; called by muse, mutect2, varscan2
- GLE1 | c.1494A>T p.A498= | Silent (SNP) | VAF 44/111 reads (40%) | catalogued as COSV59407100; called by muse, mutect2, varscan2
- GRK7 | c.1482G>T p.G494= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as COSV53822107, COSV53823680; called by muse, mutect2, varscan2
- LRRC41 | c.1872C>T p.A624= | Silent (SNP) | VAF 63/294 reads (21%) | catalogued as COSV58439400; called by muse, mutect2, varscan2
- MFAP5 | c.180T>A p.A60= | Silent (SNP) | VAF 61/189 reads (32%) | catalogued as COSV63945154; called by muse, mutect2, varscan2
- PNLIPRP3 | c.279A>T p.I93= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as COSV65047434; called by muse, mutect2, varscan2
- RALGAPB | c.144T>G p.P48= | Silent (SNP) | VAF 39/169 reads (23%) | catalogued as COSV53436026; called by muse, mutect2, varscan2
- RPS3 | c.459G>A p.V153= | Silent (SNP) | VAF 18/170 reads (11%) | catalogued as COSV53704405; called by muse, mutect2, varscan2
- RUFY3 | c.1383A>T p.A461= | Silent (SNP) | VAF 103/473 reads (22%) | catalogued as rs1387661677, COSV56912312; called by muse, mutect2, varscan2
- SERPINB3 | c.963C>T p.R321= | Silent (SNP) | VAF 30/125 reads (24%) | catalogued as rs763567283, COSV52190500; called by muse, mutect2, varscan2
- SSC4D | c.963C>G p.P321= | Silent (SNP) | VAF 35/188 reads (19%) | catalogued as rs1188070524, COSV51881777, COSV99300035; called by muse, mutect2, varscan2
- TMC4 | c.700C>T p.L234= (on ENST00000617472 / NM_001145303.3; = p.L228= on NM_144686.4) | Silent (SNP) | VAF 37/125 reads (30%) | catalogued as COSV56598798; called by muse, mutect2, varscan2
- USP9X | c.5019T>A p.L1673= | Silent (SNP) | VAF 54/170 reads (32%) | catalogued as COSV61067366; called by muse, mutect2, varscan2
- VWCE | c.2550C>G p.T850= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV57111513; called by muse, mutect2, varscan2
- ZNF536 | c.3291C>T p.T1097= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as rs202189721, COSV62821368; called by muse, mutect2, varscan2
- CDKL1 | c.367-806C>T | Intron (SNP) | VAF 17/130 reads (13%) | catalogued as COSV53579638; called by muse, mutect2, varscan2
- FAM169B | n.341G>A | RNA (SNP) | VAF 24/136 reads (18%) | catalogued as COSV60568299; called by muse, mutect2
